Gene-level copy-number profile of tumor specimen TCGA-LN-A7HZ-01A from TCGA case TCGA-LN-A7HZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 49.1 years (17,931 days).
Specimen TCGA-LN-A7HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.00a35e3c-3f6a-41ca-bc50-55346590c501.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A7HZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/94b9d5f3-9b94-4bd4-90c0-05d14d8fb3ea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 557; copy number 2: 16,032; copy number 3: 26,582; copy number 4: 9,508; copy number 5: 4,929; copy number 6: 683; copy number 7: 567; copy number 8: 514; copy number 10: 28; copy number 11: 296; copy number 12: 103; copy number 13: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A7HZ-01A-31D-A350-01): tumor purity 0.63, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr3:67,654,669–67,947,713, 1 gene (within-gene range 0–2): SUCLG2-AS1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,512 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,265,222–143,848,485, 1 gene, copy number 8 (within-gene range 4–8): SLC9A9.
- chr3:143,503,275–198,222,513, 940 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr4:43,133,867–49,062,081, 68 genes, copy number 7–12 (broad region; genes not listed).
- chr8:150,584–738,106, 19 genes, copy number 8: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1.
- chr11:68,460,731–68,615,334, 1 gene, copy number 11 (within-gene range 3–11): PPP6R3.
- chr11:68,612,899–77,637,794, 295 genes, copy number 11 (within-gene range 3–11) (broad region; genes not listed).
- chr12:25,108,289–33,923,480, 188 genes, copy number 8–13 (within-gene range 4–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 140. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
